Gene-level copy-number profile of tumor specimen TCGA-ZP-A9D2-01A from TCGA case TCGA-ZP-A9D2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 51.2 years (18,717 days).
Specimen TCGA-ZP-A9D2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.087686c0-6795-4348-b380-c12a079c4829.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZP-A9D2-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95e4cd95-ca12-4b8b-8ecc-52dc796cd679

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 13,325; copy number 2: 40,903; copy number 3: 4,737; copy number 4: 114; copy number 5: 252; copy number 6: 468.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZP-A9D2-01A-11D-A381-01): tumor purity 0.69, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:72,288,785–72,289,110, 1 gene: RPS15AP13.
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr9:110,873,263–111,038,458, 1 gene (within-gene range 0–1): LPAR1.
- chr9:111,097,325–111,284,836, 3 genes (within-gene range 0–1): RNY4P18, AL162414.1, MIR7702.
- chr9:114,323,056–114,333,251, 2 genes: ORM1, ORM2.
- chr9:132,878,027–132,991,687, 6 genes: SPACA9, TSC1, GFI1B, MIR548AW, AL593851.1, RNU7-21P.
- chr14:50,632,058–50,831,162, 6 genes (within-gene range 0–1): SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 720 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (broad region; genes not listed).
- chr7:38,256,337–38,318,861, 10 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.

Autosomal genes at a single copy (total copy number 1): 10,904. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
